Somatic mutation profile of tumor specimen TCGA-B6-A0WY-01A (aliquot TCGA-B6-A0WY-01A-11D-A10G-09) from TCGA case TCGA-B6-A0WY, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 40.5 years (14,778 days).
Specimen TCGA-B6-A0WY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12a5b48c-5759-40dc-a3c4-3019fa441d3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A0WY-10A (Blood Derived Normal), aliquot TCGA-B6-A0WY-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4ae4fb1-56ee-4e68-b754-4e7adf685a81

The open-access MAF lists 26 somatic variants for this specimen: 23 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 16, Nonsense Mutation 4, Silent 3, In Frame Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPI | c.1063G>A p.D355N | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs377070041; called by muse, mutect2, varscan2
- CHD1L | c.1395dup p.V466Sfs*16 | Frame Shift Ins (INS) | VAF 14/130 reads (11%) | catalogued as rs1461398222; called by mutect2, pindel, varscan2
- EFEMP1 | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100816924; called by muse, mutect2, varscan2
- EXD1 | c.86G>T p.S29I | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs1454579822, COSV100153765; called by muse, mutect2
- FBN1 | c.4181G>T p.G1394V | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV100354228, COSV57312093; called by muse, mutect2, varscan2
- FILIP1L | c.1678G>A p.V560I (on ENST00000354552 / NM_182909.3; = p.V320I on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs777759195, COSV58767363, COSV58771709; called by muse, mutect2
- HERC2 | c.11261C>T p.A3754V | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.478); catalogued as rs575646071, COSV55313485; called by muse, mutect2, varscan2
- KIAA2026 | c.3983C>T p.T1328I | Missense Mutation (SNP) | VAF 50/196 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as COSV67353923; called by muse, mutect2, varscan2
- KMT2B | c.4813G>T p.E1605* | Nonsense Mutation (SNP) | VAF 28/125 reads (22%) | catalogued as rs1331423540, COSV55858691; called by muse, mutect2, varscan2
- LPCAT1 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV99359193; called by muse, mutect2
- NCOR1 | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 67/235 reads (29%) | catalogued as COSV51965729; called by muse, mutect2, varscan2
- NRAP | c.3529C>T p.R1177* (on ENST00000359988 / NM_001322945.2; = p.R1142* on NM_006175.4) | Nonsense Mutation (SNP) | VAF 22/203 reads (11%) | catalogued as rs868219364, COSV63489139; called by muse, mutect2, varscan2
- OR2T33 | c.613C>G p.L205V | Missense Mutation (SNP) | VAF 29/259 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58814706; called by muse, mutect2, varscan2
- RCOR2 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 13/138 reads (9%) | catalogued as COSV100036291; called by muse, mutect2
- SLC27A3 | c.262A>C p.T88P | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.193); catalogued as COSV99670052; called by muse, mutect2
- TERF2IP | c.839G>A p.C280Y | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.854); catalogued as rs527404806, COSV55613095; called by muse, mutect2, varscan2
- TMCO5A | c.155T>A p.I52N | Missense Mutation (SNP) | VAF 14/169 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100148639; called by muse, mutect2
- TMEM150C | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.989); catalogued as rs745461497, COSV101497320; called by muse, mutect2
- UGGT2 | c.2320G>T p.G774W | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65073170; called by muse, mutect2, varscan2
- ZNF384 | c.1327A>G p.T443A (on ENST00000361959; = p.T382A on NM_133476.5) | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100158782; called by muse, mutect2
- ZNF641 | c.250G>C p.A84P | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV56389776, COSV99973573; called by muse, mutect2, varscan2
- PIK3CA | c.327_335del p.E109_I112delinsD | In Frame Del (DEL) | VAF 34/90 reads (38%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1712_1720del p.I571_L573del (on ENST00000521381 / NM_181523.3; = p.I301_L303del on NM_181504.4) | In Frame Del (DEL) | VAF 29/216 reads (13%) | called by mutect2, pindel, varscan2
- ERP27 | c.757C>T p.L253= | Silent (SNP) | VAF 32/197 reads (16%) | catalogued as COSV56762665; called by muse, mutect2, varscan2
- MIA3 | c.5010C>G p.S1670= | Silent (SNP) | VAF 18/220 reads (8%) | catalogued as rs757946349, COSV100485136; called by muse, mutect2
- RIPOR3 | c.1893T>G p.A631= | Silent (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
